Somatic mutation profile of tumor specimen 0DZY5K from CCDI case PBCURU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0DZY5K: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21e80f40-953b-474e-b0a6-e0507a522cf5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZY6G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9dcb39ea-819b-4ac1-98f4-ef05494cad5f

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NYX | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763017414; called by muse, mutect2
- TFAP2C | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 13/356 reads (4%) | catalogued as rs1209478178; called by muse, mutect2
- TTK | c.979T>G p.L327V | Missense Mutation (SNP) | VAF 19/351 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV100036494; called by muse, mutect2
- NLRP1 | c.1749G>T p.K583N | Missense Mutation (SNP) | VAF 17/258 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.124); called by muse, mutect2
- NLRP14 | c.2250T>G p.C750W | Missense Mutation (SNP) | VAF 12/364 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- RAD54L2 | c.2978C>T p.A993V | Missense Mutation (SNP) | VAF 26/520 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.164); called by muse, mutect2
- SRCIN1 | c.1364C>T p.P455L (on ENST00000621492; = p.P421L on NM_025248.3) | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- TACR3 | c.1103A>G p.K368R | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- MAP1A | c.2697C>T p.S899= | Silent (SNP) | VAF 37/268 reads (14%) | catalogued as COSV55813205; called by muse, mutect2, varscan2
- MOCOS | c.285G>A p.E95= | Silent (SNP) | VAF 40/540 reads (7%) | called by muse, mutect2
- COL4A2 | c.1433-615A>G | Intron (SNP) | VAF 27/365 reads (7%) | called by muse, mutect2
